Somatic mutation profile of tumor specimen TARGET-20-PATKYC-09A (aliquot TARGET-20-PATKYC-09A-01D) from TARGET case TARGET-20-PATKYC, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.4 years (4,172 days).
Specimen TARGET-20-PATKYC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26bb46be-7f70-4ce4-892a-a47b84cfa19c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATKYC-14A (Bone Marrow Normal), aliquot TARGET-20-PATKYC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6c78cee-fde1-4b21-b307-ab593f9a01e0

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 16/212 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- MYH11 | c.5374C>T p.R1792W | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1364355866, COSV55547525; called by muse, mutect2, varscan2
- GATA2 | c.859_860insT p.R287Lfs*97 | Frame Shift Ins (INS) | VAF 28/70 reads (40%) | called by mutect2, pindel, varscan2
- KIT | c.2466_2467insGGGGATTTTCTCCCC p.N822_Y823insGDFLP | In Frame Ins (INS) | VAF 30/172 reads (17%) | called by mutect2, pindel
